Somatic mutation profile of tumor specimen HTMCP-03-06-02044-01A (aliquot HTMCP-03-06-02044-01A-01D-4427) from CGCI case HTMCP-03-06-02044, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02044-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 609e9c1c-8175-493f-8109-37ec95c8678c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02044-10A (Blood Derived Normal), aliquot HTMCP-03-06-02044-10A-01D-4427; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/847098d9-f279-4f2e-9844-531362c7b551

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 52/192 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGBL5 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs886678213, COSV59937733; called by muse, mutect2, varscan2
- ANKS1B | c.1517G>T p.C506F | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61380503; called by muse, mutect2, varscan2
- CCDC102B | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | catalogued as rs1385101720, COSV60149472; called by muse, mutect2, varscan2
- DCAF12L2 | c.1316C>G p.P439R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100758422; called by muse, mutect2, varscan2
- INTS6 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs995578076; called by muse, mutect2, varscan2
- MYO5C | c.4111G>A p.E1371K | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1456024892, COSV99954883; called by muse, mutect2, varscan2
- NUP133 | c.1699G>C p.D567H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs767139944, COSV54575762; called by mutect2, varscan2
- PCDHB8 | c.710A>G p.N237S | Missense Mutation (SNP) | VAF 46/353 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1554281009; called by muse, mutect2, varscan2
- SLC12A2 | c.2698G>A p.V900M | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV52471629; called by muse, mutect2, varscan2
- SLCO6A1 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV65813334; called by muse, mutect2, varscan2
- WDR36 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs748219538, COSV72411102; called by mutect2, varscan2
- ADAMTSL3 | c.25T>C p.W9R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP21 | c.4670C>G p.S1557C | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ARHGEF7 | c.787G>A p.D263N (on ENST00000375741 / NM_001113511.2; = p.D85N on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- FAM214A | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT3 | c.2631T>A p.F877L | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MUC17 | c.1946T>A p.L649H | Missense Mutation (SNP) | VAF 89/754 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- NBPF14 | c.7954G>T p.E2652* | Nonsense Mutation (SNP) | VAF 55/458 reads (12%) | called by muse, mutect2, varscan2
- P3H3 | c.527C>G p.A176G | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- LSP1 | c.177G>A p.P59= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1300462314, COSV100288847, COSV61138220; called by muse, mutect2, varscan2
- PCDHB6 | c.1554C>T p.D518= | Silent (SNP) | VAF 53/289 reads (18%) | catalogued as rs1239817024; called by muse, mutect2, varscan2
- TTF2 | c.1404G>A p.K468= | Silent (SNP) | VAF 27/160 reads (17%) | catalogued as COSV101037389; called by muse, mutect2, varscan2
- TTLL12 | c.1389C>T p.D463= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as rs959039107, COSV53356987; called by muse, mutect2, varscan2
- TTN | c.55425G>A p.G18475= (on ENST00000591111; = p.G11051= on NM_003319.4) | Silent (SNP) | VAF 45/250 reads (18%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+3242G>A | Intron (SNP) | VAF 18/156 reads (12%) | catalogued as rs533262301; called by mutect2, varscan2
